Somatic mutation profile of tumor specimen BA2092D (aliquot aq-BA2092D) from BEATAML1.0 case 2194, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia with mutated NPM1; Tissue or organ of origin: Bone marrow; Age at diagnosis: 46.4 years (16,941 days).
Specimen BA2092D: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f02674a7-5982-4365-9408-4247dd890e59.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2823D (Solid Tissue Normal), aliquot aq-BA2823D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bd78349d-4fb7-4000-a4ac-ff402dffe410

The open-access MAF lists 17 somatic variants for this specimen: 12 protein-altering or splice-affecting, 3 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Silent 3, 5'UTR 2, Frame Shift Ins 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANAPC1 | c.29C>T p.T10M | Missense Mutation (SNP) | VAF 28/254 reads (11%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.994); catalogued as rs765558487; called by muse, mutect2, varscan2
- CDH24 | c.1822G>C p.A608P | Missense Mutation (SNP) | VAF 19/146 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.006); catalogued as rs754880907; called by muse, mutect2, varscan2
- MGAM2 | c.6292G>A p.V2098I | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT tolerated, low confidence (0.98); catalogued as rs185345117; called by muse, mutect2, varscan2
- SYT16 | c.703G>A p.G235R | Missense Mutation (SNP) | VAF 28/260 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs1413075127, COSV70855944; called by muse, mutect2, varscan2
- TLR7 | c.305C>T p.P102L | Missense Mutation (SNP) | VAF 14/232 reads (6%) | SIFT tolerated (0.24); PolyPhen benign (0.188); catalogued as COSV101027876, COSV66124698; called by muse, mutect2
- WDR7 | c.1672C>T p.R558C | Missense Mutation (SNP) | VAF 49/284 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs760662291, COSV99589122; called by muse, mutect2, varscan2
- ARID2 | c.3700dup p.T1234Nfs*7 | Frame Shift Ins (INS) | VAF 35/319 reads (11%) | called by mutect2, pindel, varscan2
- COL14A1 | c.4900A>T p.R1634W | Missense Mutation (SNP) | VAF 18/120 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.664); called by muse, mutect2, varscan2
- ESYT1 | c.2814del p.E939Sfs*20 | Frame Shift Del (DEL) | VAF 16/129 reads (12%) | called by mutect2, pindel, varscan2
- GCNA | c.1882C>T p.P628S | Missense Mutation (SNP) | VAF 23/177 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SERPINB11 | c.497G>C p.G166A | Missense Mutation (SNP) | VAF 18/118 reads (15%) | SIFT tolerated (0.77); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZNF490 | c.1093A>G p.K365E | Missense Mutation (SNP) | VAF 23/186 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.849); called by muse, mutect2, varscan2
- ANKS1B | c.2844C>T p.H948= (on ENST00000547776 / NM_152788.4; = p.H174= on NM_020140.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 19/120 reads (16%) | catalogued as rs374794796; called by muse, mutect2, varscan2
- EGLN1 | c.417T>A p.A139= | Silent (SNP) | VAF 3/11 reads (27%) | called by muse, mutect2
- KIAA1217 | c.4644C>T p.H1548= | Silent (SNP) | VAF 20/185 reads (11%) | catalogued as rs371832921; called by muse, mutect2
- LFNG | c.-4C>A | 5'UTR (SNP) | VAF 3/39 reads (8%) | called by muse, mutect2
- UPF3B | c.-30G>A | 5'UTR (SNP) | VAF 14/115 reads (12%) | called by muse, mutect2, varscan2
